Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UZ-01A (Primary Tumor).

(MM/DD/YYYY)

ICD-O-3

Adenocarcinoma, mucinous
endocervical type 8482/3

Site: Cervix NOS C53.9

JW 5/7/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Uterus:

Mucinous adenocarcinoma of endocervical type of cervix, histologic grade 2, infiltrating until deep third of cervical wall (8.0 mm deep and 35 mm of extension). Uninvolved margins.

Right and left parametria uninvolved by neoplasia.

Right and left uterine tubes uninvolved by neoplasia.

Right and left ovaries uninvolved by neoplasia.

Left pelvic lymph nodes:

Absent of neoplasia (0/12)

Right pelvic lymph nodes:

Absent of neoplasia (0/14)

Criteria	JW 12/9/13	Yes	No

Source: NCI Genomic Data Commons file 8a32f88d-5376-4a36-ae89-f07ce4899065 (TCGA-VS-A9UZ.F340AC28-F1AC-4AC3-9C7D-CAC4F3EE04E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).